Somatic mutation profile of tumor specimen TCGA-TM-A84F-01A (aliquot TCGA-TM-A84F-01A-11D-A36O-08) from TCGA case TCGA-TM-A84F, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.6 years (17,744 days).
Specimen TCGA-TM-A84F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd05c123-3e8b-4b5c-b1c3-2f790b06e2de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84F-10A (Blood Derived Normal), aliquot TCGA-TM-A84F-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24a1e3fb-622f-4f61-9b68-60e6743a207a

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 3, Frame Shift Del 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ARHGEF15 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs747278375, COSV100730045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CWC22 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748093590, COSV55427056; called by muse, varscan2
- DUOX2 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs545643570, COSV101199757; called by muse, mutect2, varscan2
- HERC1 | c.11542C>G p.P3848A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV101496561; called by muse, mutect2, varscan2
- IQGAP1 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs980602514, COSV51587955; called by muse, mutect2, varscan2
- MED1 | c.867_869del p.S290del | In Frame Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs1306980533; called by pindel, varscan2
- MEPE | c.122del p.N41Tfs*14 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs768254676; called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.1620C>A p.H540Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV100544206; called by muse, mutect2
- ROBO2 | c.2641T>C p.Y881H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100166715; called by muse, mutect2, varscan2
- TTYH3 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as rs1409009371, COSV51863000; called by muse, mutect2, varscan2
- UBR4 | c.8314G>C p.E2772Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as COSV100920781; called by muse, mutect2, varscan2
- ZNF792 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs768051045, COSV101289704; called by muse, mutect2, varscan2
- ABCA9 | c.1766T>C p.I589T | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- GSX1 | c.654dup p.A219Cfs*25 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- MYT1 | c.2524dup p.L842Pfs*9 | Frame Shift Ins (INS) | VAF 53/190 reads (28%) | called by mutect2, pindel, varscan2
- TCF12 | c.822dup p.S276Efs*62 | Frame Shift Ins (INS) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- L1TD1 | c.1701T>C p.D567= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100776581; called by muse, mutect2, varscan2
- MYH7B | c.3969G>A p.T1323= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs367556657; called by muse, mutect2, varscan2
- TTN | c.67752G>A p.P22584= (on ENST00000591111; = p.P15160= on NM_003319.4) | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs374314698, COSV59871887; called by muse, mutect2, varscan2
- HERC2P3 | n.1245T>A | RNA (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
